Somatic mutation profile of tumor specimen C3L-02860-01 (aliquot CPT0389250006) from CPTAC case C3L-02860, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 73.4 years (26,812 days).
Specimen C3L-02860-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1a1e026-a341-485e-b4fd-980778990db9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02860-31 (Blood Derived Normal), aliquot CPT0389300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/662cfe7d-3143-42bf-bcb2-05d80ce29bad

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, 3'UTR 2, Nonsense Mutation 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4785C>A p.F1595L | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54331446, COSV54348753; called by muse, mutect2
- MAP1S | c.2905C>T p.Q969* | Nonsense Mutation (SNP) | VAF 9/236 reads (4%) | catalogued as COSV60722642; called by muse, mutect2
- ABCC2 | c.4079T>A p.I1360N | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCNA2 | c.1118C>G p.P373R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- DNAH7 | c.11126G>C p.G3709A | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- DSC3 | c.2070A>T p.K690N | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2
- FA2H | c.602C>A p.S201* | Nonsense Mutation (SNP) | VAF 28/370 reads (8%) | called by muse, mutect2
- INTS3 | c.1413C>G p.H471Q | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.143); called by muse, mutect2
- LRRC59 | c.724A>G p.T242A | Missense Mutation (SNP) | VAF 12/325 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- POU2F3 | c.326A>T p.Q109L | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, mutect2
- PRKCA | c.85A>C p.K29Q | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2
- SFRP2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2
- TCF20 | c.4897C>A p.P1633T | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TET2 | c.4386G>C p.K1462N | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TYMP | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 21/560 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- XPC | c.2034-8T>C | Splice Region (SNP) | VAF 12/86 reads (14%) | called by mutect2, varscan2
- GOLGA8S | c.1062G>A p.E354= | Silent (SNP) | VAF 18/718 reads (3%) | called by muse, mutect2
- HDLBP | c.2322C>A p.I774= | Silent (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- SMARCA1 | c.1978C>T p.L660= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2
- MRPS25 | c.*2538C>T | 3'UTR (SNP) | VAF 20/242 reads (8%) | catalogued as rs772862365; called by muse, mutect2
- TGFBR3 | c.*316T>A | 3'UTR (SNP) | VAF 15/364 reads (4%) | called by muse, mutect2
- TINF2 | c.193-11G>A | Intron (SNP) | VAF 13/393 reads (3%) | called by muse, mutect2
